Gene-level copy-number profile of tumor specimen TCGA-WB-A81Q-01A from TCGA case TCGA-WB-A81Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 45.0 years (16,422 days).
Specimen TCGA-WB-A81Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.bccd2bee-11e8-4af8-8d39-0cac0c69a876.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WB-A81Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/366a3fcf-37ae-45b6-9869-a2e7c8cc5992

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 10,302; copy number 2: 45,606; copy number 3: 3,907.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WB-A81Q-01A-11D-A35H-01): tumor purity 0.88, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:31,090,787–31,095,450, 2 genes: AC138207.2, MIR4733.
- chr17:31,133,182–31,138,518, 1 gene: AC079915.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,915. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
